Somatic mutation profile of tumor specimen BA2161D (aliquot aq-BA2161D) from BEATAML1.0 case 2082, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.1 years (19,771 days).
Specimen BA2161D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9aecef6-9da5-4440-8ee3-8302eb2381b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2637D (Solid Tissue Normal), aliquot aq-BA2637D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2114fa3b-2db0-4e98-b648-431608bdc88a

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDHGB6 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV53908702; called by muse, mutect2, varscan2
- PIK3CA | c.2593G>A p.G865S | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV56006417; called by mutect2, varscan2
- TRIM49C | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 68/515 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs776721340; called by muse, varscan2
- ALMS1 | c.10153A>G p.R3385G | Missense Mutation (SNP) | VAF 11/322 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2
- SAMD3 | c.1432A>G p.I478V | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLCO1B3 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- VWA3A | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM110B | c.312C>T p.H104= | Silent (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- OPCML | c.624C>T p.V208= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs1177291969, COSV59424033; called by mutect2, varscan2
- FAAP20 | chr1:2198980 C>A | 5'Flank (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- SCNN1G | c.-37G>A | 5'UTR (SNP) | VAF 33/153 reads (22%) | catalogued as rs761303892, COSV100264072; called by muse, mutect2, varscan2
